Somatic mutation profile of tumor specimen ALCH-AC3M-TTP1-A (aliquot ALCH-AC3M-TTP1-A-1-0-D-A49J-36) from ALCHEMIST case ALCH-AC3M, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.3 years (24,951 days).
Specimen ALCH-AC3M-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cf9e232-90c6-4417-b65c-e4e00d4ae29b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AC3M-NB1-A (Blood Derived Normal), aliquot ALCH-AC3M-NB1-A-1-0-D-A49J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/587f4877-6b1e-4943-bc86-03123f7c3d25

The open-access MAF lists 266 somatic variants for this specimen: 181 protein-altering or splice-affecting, 55 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 55, Nonsense Mutation 18, Intron 10, Splice Site 5, RNA 5, 3'UTR 4, 3'Flank 4, 5'Flank 4, 5'UTR 3, Splice Region 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>G p.H83D | Missense Mutation (SNP) | VAF 29/404 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic; called by muse, mutect2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 247/1332 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 54/1310 reads (4%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as rs1048095040, CM100445, CM951235, COSV52848377, COSV53866546; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 112/483 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAD1 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1248212922; called by muse, varscan2
- ADARB1 | c.1648C>T p.R550W (on ENST00000360697 / NM_001346687.2; = p.R510W on NM_001112.4) | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62348097; called by muse, mutect2
- AK5 | c.186G>T p.Q62H (on ENST00000354567 / NM_174858.3; = p.Q36H on NM_012093.4) | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100481458; called by muse, mutect2, varscan2
- ALDH9A1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV100699273; called by muse, mutect2
- AP4M1 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 67/394 reads (17%) | catalogued as rs201424846; called by muse, mutect2, varscan2
- BEND2 | c.1733C>G p.S578C | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.237); catalogued as COSV66217150; called by muse, mutect2
- C7 | c.400C>G p.P134A | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57479700; called by muse, mutect2, varscan2
- CAPSL | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1479892478; called by muse, mutect2, varscan2
- CORIN | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 58/384 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs369280273; called by muse, mutect2, varscan2
- CREB3L3 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 131/944 reads (14%) | catalogued as rs540604714, COSV99314453; called by muse, mutect2, varscan2
- CREBBP | c.2077C>G p.P693A | Missense Mutation (SNP) | VAF 64/437 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.281); catalogued as CD158352; called by muse, mutect2, varscan2
- CSMD3 | c.1633G>T p.V545L (on ENST00000297405 / NM_001363185.1; = p.V441L on NM_052900.3) | Missense Mutation (SNP) | VAF 62/576 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV99826970; called by muse, mutect2, varscan2
- CYP4F11 | c.1441G>T p.V481F | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56128032; called by muse, mutect2, varscan2
- DAB1 | c.1757C>A p.A586D (on ENST00000371231; = p.A553D on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs751379532; called by muse, mutect2, varscan2
- DMD | c.1021C>A p.L341M | Missense Mutation (SNP) | VAF 42/361 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55881876; called by muse, mutect2, varscan2
- DNAH7 | c.8737G>T p.G2913* | Nonsense Mutation (SNP) | VAF 37/204 reads (18%) | catalogued as COSV56781668; called by muse, mutect2, varscan2
- EML6 | c.2773G>A p.V925M | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1297054444; called by muse, mutect2
- ERICH3 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 22/617 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as rs1217409812; called by muse, mutect2
- ESAM | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs773732062, COSV54034062; called by mutect2, varscan2
- FANCC | c.1534-1G>C p.X512_splice | Splice Site (SNP) | VAF 35/1272 reads (3%) | catalogued as rs1364238660; called by muse, mutect2
- GAB3 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 43/514 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200095289; called by muse, mutect2
- GABRB3 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 104/641 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV54648691; called by muse, mutect2, varscan2
- GRIK3 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 29/121 reads (24%) | catalogued as rs971243250, COSV66142243; called by muse, mutect2, varscan2
- GUCY1A2 | c.912C>A p.N304K | Missense Mutation (SNP) | VAF 50/333 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as rs763966532; called by muse, mutect2, varscan2
- HAPLN1 | c.576C>A p.D192E | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99164994; called by muse, mutect2, varscan2
- HMCN1 | c.3649C>T p.H1217Y | Missense Mutation (SNP) | VAF 114/1006 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.121); catalogued as COSV99633559; called by muse, mutect2, varscan2
- KCNT2 | c.2743G>T p.G915* | Nonsense Mutation (SNP) | VAF 49/458 reads (11%) | catalogued as COSV99655057; called by muse, mutect2, varscan2
- KLF17 | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.073); catalogued as COSV64856162; called by muse, mutect2, varscan2
- KLHL4 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 132/504 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100910128; called by muse, mutect2, varscan2
- KRTAP10-10 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 56/649 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV59956750; called by muse, mutect2
- LAMA2 | c.4959G>A p.R1653= | Splice Region (SNP) | VAF 114/527 reads (22%) | catalogued as COSV70352304; called by muse, mutect2, varscan2
- LILRA2 | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 60/751 reads (8%) | catalogued as COSV99254101, COSV99254151; called by muse, mutect2
- LRIT2 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as COSV100928301; called by muse, mutect2, varscan2
- LYPD2 | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV63649493; called by muse, mutect2, varscan2
- MAGIX | c.885G>C p.Q295H | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.885); catalogued as rs1557098023; called by muse, mutect2
- MALRD1 | c.4637C>G p.S1546C | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs911000982; called by muse, mutect2
- MFSD2B | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 79/476 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57855595; called by muse, mutect2, varscan2
- MYH13 | c.3424G>T p.D1142Y | Missense Mutation (SNP) | VAF 97/465 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99351577; called by muse, mutect2, varscan2
- NLRP12 | c.2223C>A p.N741K | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.211); catalogued as rs781690422; called by muse, mutect2, varscan2
- NLRP3 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 88/718 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV100276704; called by muse, mutect2, varscan2
- NOS1 | c.2935G>T p.V979L | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV57608726; called by muse, mutect2, varscan2
- NPHS1 | c.741G>T p.W247C | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs758490906; called by muse, mutect2, varscan2
- NPTX2 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.545); catalogued as COSV55718898; called by muse, mutect2, varscan2
- OLFM4 | c.39C>G p.F13L | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV54581101, COSV99524264; called by muse, mutect2
- OR2L13 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63552858; called by muse, mutect2, varscan2
- OR5T1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs371059328, COSV57302248; called by muse, mutect2
- OTOF | c.4415C>A p.A1472D (on ENST00000272371 / NM_194248.3; = p.A705D on NM_004802.4) | Missense Mutation (SNP) | VAF 82/814 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.129); catalogued as COSV55511216; called by muse, mutect2
- PAH | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 83/532 reads (16%) | catalogued as CM068056; called by muse, mutect2, varscan2
- PC | c.1582G>A p.V528I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs200433873, COSV58920866; called by muse, mutect2
- PIKFYVE | c.4262C>T p.S1421L | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as COSV52237335; called by muse, mutect2
- PLSCR5 | c.492C>A p.Y164* | Nonsense Mutation (SNP) | VAF 78/387 reads (20%) | catalogued as COSV99068681; called by muse, mutect2, varscan2
- PTPRR | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 154/726 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs778886611; called by muse, varscan2
- RORB | c.586G>A p.D196N (on ENST00000396204 / NM_001365023.1; = p.D185N on NM_006914.4) | Missense Mutation (SNP) | VAF 30/325 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as rs746564329; called by muse, mutect2
- SEMA3D | c.1601G>A p.C534Y | Missense Mutation (SNP) | VAF 48/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99406200; called by muse, mutect2, varscan2
- SERPINI2 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 66/792 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV52987417; called by muse, mutect2
- SFRP4 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.908); catalogued as COSV52258301; called by muse, mutect2
- SHANK1 | c.6254C>T p.P2085L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.091); catalogued as rs924451909; called by muse, mutect2
- SP110 | c.1241del p.K414Rfs*12 | Frame Shift Del (DEL) | VAF 60/584 reads (10%) | catalogued as rs1559146826; called by mutect2, varscan2
- SPAG1 | c.1535+1G>C p.X512_splice | Splice Site (SNP) | VAF 29/230 reads (13%) | catalogued as rs1444081525; called by muse, mutect2, varscan2
- SPATA31D1 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs569655832, COSV61193279; called by muse, mutect2, varscan2
- SREBF2 | c.2434A>G p.I812V | Missense Mutation (SNP) | VAF 34/1327 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1569408183; called by muse, mutect2
- TBC1D9B | c.1865G>T p.R622L | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs747331720, COSV104417295; called by muse, mutect2, varscan2
- TGIF2LX | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 141/1708 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV52215049; called by muse, mutect2
- TP53 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 36/883 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52674807, COSV53408653; called by muse, mutect2
- TRIM41 | c.1676A>G p.Y559C | Missense Mutation (SNP) | VAF 99/676 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757149132; called by muse, mutect2, varscan2
- TRIO | c.2464A>T p.T822S | Missense Mutation (SNP) | VAF 172/587 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.956); catalogued as COSV100711249; called by muse, mutect2, varscan2
- USP36 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1276717923, COSV61751830; called by muse, mutect2
- VPS13B | c.8637G>T p.Q2879H | Missense Mutation (SNP) | VAF 69/544 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs771886409, COSV62147654; called by muse, mutect2, varscan2
- ABCA2 | c.5260G>T p.V1754L (on ENST00000614293; = p.V1724L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.22); called by muse, mutect2
- ABCF1 | c.1728G>C p.K576N (on ENST00000326195 / NM_001025091.2; = p.K538N on NM_001090.3) | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- ADAM2 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- AGAP1 | c.1783G>T p.E595* (on ENST00000304032 / NM_001037131.3; = p.E542* on NM_014914.5) | Nonsense Mutation (SNP) | VAF 60/531 reads (11%) | called by muse, mutect2, varscan2
- AL592490.1 | c.1199C>G p.A400G | Missense Mutation (SNP) | VAF 18/438 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.212); called by muse, mutect2
- ALDH1A2 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 62/389 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ARHGAP4 | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- ARMCX5 | c.519G>C p.W173C | Missense Mutation (SNP) | VAF 58/498 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ARSH | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 26/475 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ASCC3 | c.2743A>T p.K915* | Nonsense Mutation (SNP) | VAF 26/464 reads (6%) | called by muse, mutect2
- ASTN2 | c.1283T>A p.L428Q (on ENST00000313400 / NM_001365069.1; = p.L377Q on NM_014010.5) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.14); called by muse, mutect2
- ASXL3 | c.5197G>T p.A1733S | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BARX1 | c.79C>G p.R27G | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- BRWD3 | c.2309C>G p.S770C | Missense Mutation (SNP) | VAF 18/489 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.497); called by muse, mutect2
- C10orf71 | c.3877C>A p.Q1293K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CACNG3 | c.927C>A p.N309K | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, varscan2
- CAMSAP2 | c.3904G>A p.V1302I (on ENST00000236925 / NM_001297707.2; = p.V1291I on NM_203459.3) | Missense Mutation (SNP) | VAF 118/633 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKL2 | c.914A>T p.Q305L | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFAP65 | c.436G>T p.E146* (on ENST00000341552 / NM_194302.4; = p.E81* on NM_152389.4) | Nonsense Mutation (SNP) | VAF 79/446 reads (18%) | called by muse, mutect2, varscan2
- DDI1 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 155/846 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK1 | c.3292G>C p.E1098Q | Missense Mutation (SNP) | VAF 19/456 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- DOCK9 | c.3547G>A p.D1183N (on ENST00000376460 / NM_001366676.2; = p.D1184N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/389 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2
- DST | c.17572G>T p.A5858S (on ENST00000361203 / NM_001374722.1; = p.A3555S on NM_015548.5) | Missense Mutation (SNP) | VAF 62/271 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DTWD2 | c.62C>G p.S21* | Nonsense Mutation (SNP) | VAF 17/329 reads (5%) | called by muse, mutect2
- FLNA | c.4148C>A p.A1383D | Missense Mutation (SNP) | VAF 63/490 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FNDC7 | c.1176G>T p.W392C | Missense Mutation (SNP) | VAF 56/388 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMD4A | c.1798G>C p.D600H | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.374); called by muse, mutect2
- FRY | c.2922G>C p.L974F | Missense Mutation (SNP) | VAF 27/819 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2
- GAS2L1 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GK3P | c.631C>G p.H211D | Missense Mutation (SNP) | VAF 28/909 reads (3%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.643); called by muse, mutect2
- GLG1 | c.3388G>T p.G1130C | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GRIA3 | c.1570C>A p.P524T | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HECTD4 | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 48/792 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HMCN2 | c.2334G>T p.Q778H | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.014); called by muse, mutect2
- HMCN2 | c.10594C>A p.Q3532K | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- HNRNPA1L2 | c.390A>T p.K130N | Missense Mutation (SNP) | VAF 188/894 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- HSPA4 | c.2128A>C p.M710L | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- IFNAR1 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 70/388 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- IRAK1 | c.160A>T p.T54S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IRF6 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF1A | c.939G>T p.W313C | Missense Mutation (SNP) | VAF 27/370 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIR3DL3 | c.320C>G p.S107W | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRTAP19-6 | c.133C>A p.R45S | Missense Mutation (SNP) | VAF 52/548 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); called by muse, mutect2
- LMOD2 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.836); called by muse, mutect2
- LPO | c.1346G>A p.S449N | Missense Mutation (SNP) | VAF 178/893 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC8D | c.1339A>G p.R447G | Missense Mutation (SNP) | VAF 11/295 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2
- MACF1 | c.18636+1G>T p.X6212_splice (on ENST00000372915; = p.X4257_splice on NM_012090.5) | Splice Site (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- MROH5 | c.1819C>A p.H607N | Missense Mutation (SNP) | VAF 48/368 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MUC12 | c.1345C>G p.H449D (on ENST00000379442; = p.H306D on NM_001164462.1) | Missense Mutation (SNP) | VAF 32/954 reads (3%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.609); called by muse, mutect2
- MXRA5 | c.1825C>A p.L609I | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MYBL2 | c.2059C>A p.R687S | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MYRIP | c.2497T>A p.S833T | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- NELL1 | c.1280G>T p.G427V | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); called by muse, mutect2
- NR6A1 | c.739G>T p.D247Y (on ENST00000487099 / NM_033334.4; = p.D242Y on NM_001489.5) | Missense Mutation (SNP) | VAF 61/460 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OCRL | c.1433A>C p.K478T | Missense Mutation (SNP) | VAF 24/708 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR4D2 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 149/1800 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR4M1 | c.392A>T p.H131L | Missense Mutation (SNP) | VAF 65/472 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- OSBPL1A | c.1911A>T p.R637= (on ENST00000319481 / NM_080597.4; = p.R124= on NM_018030.4) | Splice Region (SNP) | VAF 20/217 reads (9%) | called by muse, mutect2
- PABPC1L | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PAM | c.1364G>C p.R455T | Missense Mutation (SNP) | VAF 27/615 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PARP1 | c.1600G>T p.D534Y | Missense Mutation (SNP) | VAF 124/1134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCDHA3 | c.1895G>A p.S632N | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PHF20L1 | c.2106G>T p.L702F | Missense Mutation (SNP) | VAF 66/488 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PHKA2 | c.845A>T p.E282V | Missense Mutation (SNP) | VAF 69/604 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- PNP | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 34/826 reads (4%) | called by muse, mutect2
- POLE | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 30/881 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2
- PPFIA4 | c.1124T>G p.I375S | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2
- PSMD12 | c.63C>A p.S21R | Missense Mutation (SNP) | VAF 86/398 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PTBP2 | c.983C>G p.A328G (on ENST00000426398 / NM_001300986.2; = p.A320G on NM_021190.4) | Missense Mutation (SNP) | VAF 53/420 reads (13%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PTPRR | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 156/716 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- QTRT1 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 65/407 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RECQL4 | c.2852G>A p.G951E | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.315); called by muse, mutect2
- SBNO2 | c.3166A>G p.K1056E | Missense Mutation (SNP) | VAF 66/446 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.242); called by muse, varscan2
- SBSN | c.1204G>C p.D402H | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2
- SEMA3F | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2
- SLC17A1 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2
- SLC24A4 | c.1625C>A p.T542N | Missense Mutation (SNP) | VAF 23/580 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- SLC26A7 | c.796-2A>T p.X266_splice | Splice Site (SNP) | VAF 12/125 reads (10%) | called by muse, mutect2
- SLC38A3 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC43A3 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 25/830 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC6A9 | c.943-2A>T p.X315_splice (on ENST00000360584 / NM_201649.4; = p.X261_splice on NM_006934.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 19/181 reads (10%) | called by muse, mutect2
- SLITRK4 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- SNX30 | c.381T>A p.Y127* | Nonsense Mutation (SNP) | VAF 40/271 reads (15%) | called by muse, mutect2, varscan2
- SOS2 | c.3136G>T p.G1046C | Missense Mutation (SNP) | VAF 58/384 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- SPATA31A1 | c.3493G>T p.G1165* | Nonsense Mutation (SNP) | VAF 226/2043 reads (11%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.3721G>T p.A1241S | Missense Mutation (SNP) | VAF 114/1367 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SSC5D | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAS2R16 | c.751C>A p.L251I | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TBCE | c.1228A>C p.K410Q (on ENST00000366601; = p.K473Q on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 304/1470 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TENM2 | c.3085C>G p.P1029A (on ENST00000518659 / NM_001122679.2; = p.P797A on NM_001080428.3) | Missense Mutation (SNP) | VAF 40/685 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- TFAP2D | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- TIAM1 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- TIFAB | c.91C>A p.H31N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); called by muse, mutect2
- TMEM184B | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TMEM74 | c.149C>A p.P50Q | Missense Mutation (SNP) | VAF 43/395 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRIM9 | c.2012C>G p.A671G | Missense Mutation (SNP) | VAF 182/1037 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UCKL1 | c.113+4G>A | Splice Region (SNP) | VAF 16/215 reads (7%) | called by muse, mutect2
- USH1C | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 152/798 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- WDPCP | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 39/497 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- WDR88 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 50/690 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2
- WNT16 | c.436G>C p.E146Q (on ENST00000222462 / NM_057168.2; = p.E136Q on NM_016087.2) | Missense Mutation (SNP) | VAF 33/860 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZFPM2 | c.3388A>T p.N1130Y | Missense Mutation (SNP) | VAF 73/659 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF154 | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 57/508 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- ZNF496 | c.1383G>T p.K461N | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZNF577 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 51/413 reads (12%) | called by muse, mutect2, varscan2
- ZNF674 | c.1178G>T p.S393I | Missense Mutation (SNP) | VAF 69/992 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2
- ZNF726 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 54/358 reads (15%) | called by muse, mutect2, varscan2
- ZNF729 | c.162G>T p.M54I | Missense Mutation (SNP) | VAF 63/318 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804A | c.1567G>T p.V523F | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- ABCA2 | c.5259G>T p.A1753= (on ENST00000614293; = p.A1723= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as rs1002248853; called by muse, mutect2
- ART1 | c.492C>T p.L164= | Silent (SNP) | VAF 24/308 reads (8%) | called by muse, mutect2
- ATP8A2 | c.568C>T p.L190= | Silent (SNP) | VAF 40/260 reads (15%) | catalogued as rs756492691; called by muse, mutect2, varscan2
- B3GNT3 | c.126G>T p.A42= | Silent (SNP) | VAF 44/312 reads (14%) | catalogued as COSV59437768; called by muse, mutect2, varscan2
- BRINP2 | c.1293C>T p.T431= | Silent (SNP) | VAF 45/178 reads (25%) | called by muse, mutect2, varscan2
- C2orf16 | c.1863C>A p.A621= | Silent (SNP) | VAF 13/155 reads (8%) | called by muse, mutect2
- C9 | c.1335C>A p.L445= | Silent (SNP) | VAF 80/547 reads (15%) | called by muse, mutect2, varscan2
- CD19 | c.1089C>T p.R363= | Silent (SNP) | VAF 8/160 reads (5%) | catalogued as rs966035942; called by muse, mutect2
- CFAP47 | c.2097G>T p.A699= | Silent (SNP) | VAF 50/385 reads (13%) | catalogued as rs778565336, COSV52880140; called by muse, mutect2, varscan2
- CLCN5 | c.1089G>T p.V363= | Silent (SNP) | VAF 36/175 reads (21%) | called by muse, mutect2, varscan2
- ERBIN | c.372A>G p.V124= | Silent (SNP) | VAF 39/255 reads (15%) | called by muse, mutect2, varscan2
- EVC2 | c.2172G>C p.L724= | Silent (SNP) | VAF 40/669 reads (6%) | called by muse, mutect2
- FAM120C | c.2232C>A p.A744= | Silent (SNP) | VAF 60/497 reads (12%) | catalogued as COSV100070527; called by muse, mutect2, varscan2
- FER1L5 | c.156C>G p.L52= | Silent (SNP) | VAF 18/379 reads (5%) | called by muse, mutect2
- FNDC8 | c.939G>A p.R313= | Silent (SNP) | VAF 41/560 reads (7%) | catalogued as rs148514334; called by muse, mutect2
- GP5 | c.636G>T p.G212= | Silent (SNP) | VAF 52/656 reads (8%) | called by muse, mutect2
- GPR152 | c.630C>T p.V210= | Silent (SNP) | VAF 62/345 reads (18%) | called by muse, mutect2, varscan2
- H2BC12 | c.138G>C p.L46= | Silent (SNP) | VAF 56/818 reads (7%) | catalogued as COSV63617070; called by muse, mutect2
- IGKV6D-21 | c.219C>G p.S73= | Silent (SNP) | VAF 67/742 reads (9%) | called by muse, mutect2
- IRS4 | c.3450C>A p.A1150= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV64532512; called by muse, mutect2, varscan2
- KAT6A | c.990C>T p.R330= | Silent (SNP) | VAF 77/660 reads (12%) | called by muse, mutect2, varscan2
- KCNH3 | c.1803C>A p.A601= | Silent (SNP) | VAF 77/310 reads (25%) | called by muse, mutect2, varscan2
- KCTD19 | c.210C>G p.L70= | Silent (SNP) | VAF 40/758 reads (5%) | called by muse, mutect2
- LAMA1 | c.2565G>T p.V855= | Silent (SNP) | VAF 111/677 reads (16%) | called by muse, mutect2, varscan2
- LAMB4 | c.841C>A p.R281= | Silent (SNP) | VAF 64/348 reads (18%) | catalogued as rs751482652, COSV104391500, COSV52715777; called by muse, mutect2, varscan2
- LDHD | c.450C>T p.S150= | Silent (SNP) | VAF 17/222 reads (8%) | catalogued as rs762825172; called by muse, mutect2
- LVRN | c.2952G>A p.A984= | Silent (SNP) | VAF 51/233 reads (22%) | catalogued as rs373152073; called by muse, mutect2, varscan2
- MROH1 | c.3453G>A p.A1151= | Silent (SNP) | VAF 18/224 reads (8%) | catalogued as rs1337637829; called by muse, mutect2
- MROH2B | c.1680G>A p.L560= | Silent (SNP) | VAF 11/175 reads (6%) | catalogued as rs1387261591, COSV68186603; called by muse, mutect2
- MROH5 | c.1818G>C p.V606= | Silent (SNP) | VAF 49/368 reads (13%) | called by muse, mutect2, varscan2
- MYH4 | c.330C>T p.Y110= | Silent (SNP) | VAF 35/255 reads (14%) | catalogued as rs756653851; called by muse, mutect2, varscan2
- NADK | c.849G>C p.L283= | Silent (SNP) | VAF 13/301 reads (4%) | called by muse, mutect2
- NAV3 | c.3372G>T p.V1124= | Silent (SNP) | VAF 103/670 reads (15%) | catalogued as COSV57074549; called by muse, mutect2, varscan2
- NMBR | c.30G>T p.S10= | Silent (SNP) | VAF 30/139 reads (22%) | called by muse, varscan2
- PCDHGB3 | c.1536G>A p.G512= | Silent (SNP) | VAF 22/410 reads (5%) | catalogued as rs755224038, COSV53915665; called by muse, mutect2
- PCDHGB6 | c.1194C>A p.S398= | Silent (SNP) | VAF 70/448 reads (16%) | called by muse, mutect2, varscan2
- PGM1 | c.1515C>T p.S505= | Silent (SNP) | VAF 45/1016 reads (4%) | catalogued as rs61760978; ClinVar: likely benign; called by muse, mutect2
- PIKFYVE | c.5685C>T p.F1895= | Silent (SNP) | VAF 32/734 reads (4%) | called by muse, mutect2
- PPFIA1 | c.12G>A p.E4= | Silent (SNP) | VAF 42/207 reads (20%) | called by muse, mutect2, varscan2
- PUS7 | c.273G>A p.E91= | Silent (SNP) | VAF 81/575 reads (14%) | catalogued as rs752320733; called by muse, mutect2, varscan2
- PWWP2B | c.111G>A p.L37= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs774165126; called by muse, mutect2, varscan2
- RPS6KA6 | c.1062A>G p.P354= | Silent (SNP) | VAF 22/257 reads (9%) | called by muse, mutect2
- SCN2A | c.855T>C p.N285= | Silent (SNP) | VAF 46/488 reads (9%) | called by muse, mutect2
- SLC1A3 | c.1224G>A p.L408= | Silent (SNP) | VAF 72/872 reads (8%) | called by muse, mutect2
- SORCS3 | c.1971G>T p.G657= | Silent (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- TAS2R16 | c.354G>C p.L118= | Silent (SNP) | VAF 27/414 reads (7%) | catalogued as COSV50797876; called by muse, mutect2
- TGIF2LX | c.531G>T p.S177= | Silent (SNP) | VAF 372/1230 reads (30%) | called by muse, mutect2, varscan2
- TMEM260 | c.12G>A p.L4= | Silent (SNP) | VAF 25/362 reads (7%) | called by muse, mutect2
- TPBGL | c.870C>T p.A290= | Silent (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- TPP2 | c.2847C>T p.F949= | Silent (SNP) | VAF 37/139 reads (27%) | called by muse, mutect2, varscan2
- TRO | c.3993G>A p.L1331= | Silent (SNP) | VAF 14/306 reads (5%) | called by muse, mutect2
- TSPAN11 | c.447C>A p.L149= | Silent (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- ZFHX4 | c.2841C>G p.L947= | Silent (SNP) | VAF 14/390 reads (4%) | called by muse, mutect2
- ZGRF1 | c.258C>T p.V86= | Silent (SNP) | VAF 13/243 reads (5%) | called by muse, mutect2
- ZNF880 | c.111G>T p.V37= | Silent (SNP) | VAF 76/455 reads (17%) | called by muse, mutect2, varscan2
- AC044798.1 | n.122C>G | RNA (SNP) | VAF 18/336 reads (5%) | called by muse, mutect2
- ATP1A3 | c.3053-62C>A | Intron (SNP) | VAF 87/827 reads (11%) | called by muse, mutect2, varscan2
- B3GNTL1 | c.409-400G>T | Intron (SNP) | VAF 51/277 reads (18%) | called by muse, mutect2, varscan2
- CACNB3 | chr12:48815686 T>A | 5'Flank (SNP) | VAF 21/652 reads (3%) | called by muse, mutect2
- CIAO3 | c.163-308C>T | Intron (SNP) | VAF 62/692 reads (9%) | catalogued as rs1401959150; called by muse, mutect2
- CLPTM1 | c.*121C>T | 3'UTR (SNP) | VAF 8/150 reads (5%) | catalogued as rs1033696477; called by muse, mutect2
- DPYD | c.*11G>A | 3'UTR (SNP) | VAF 24/838 reads (3%) | catalogued as COSV100928383; called by muse, mutect2
- DTNBP1 | c.811+590C>G | Intron (SNP) | VAF 32/630 reads (5%) | called by muse, mutect2
- FKBP10 | c.1256+41C>T | Intron (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2
- FKBP6 | c.-185G>T | 5'UTR (SNP) | VAF 36/359 reads (10%) | called by muse, mutect2, varscan2
- FLJ40288 | n.746C>T | RNA (SNP) | VAF 46/378 reads (12%) | called by muse, varscan2
- FLJ40288 | n.818C>T | RNA (SNP) | VAF 70/484 reads (14%) | called by muse, varscan2
- GALNT13 | c.1396-760C>T | Intron (SNP) | VAF 6/26 reads (23%) | catalogued as rs1485205423; called by muse, mutect2
- GPRC5B | chr16:19885215 C>G | 5'Flank (SNP) | VAF 18/559 reads (3%) | catalogued as rs1042845075; called by muse, mutect2
- LINC01551 | n.1254+18603G>C | Intron (SNP) | VAF 65/329 reads (20%) | called by muse, mutect2, varscan2
- LINC01619 | chr12:91989136 T>G | 5'Flank (SNP) | VAF 30/562 reads (5%) | called by muse, mutect2
- MTRNR2L1 | c.*9G>T | 3'UTR (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- NXF5 | n.1378G>T | RNA (SNP) | VAF 55/486 reads (11%) | catalogued as COSV99534716; called by muse, mutect2, varscan2
- OR2W5 | n.737A>T | RNA (SNP) | VAF 63/595 reads (11%) | called by muse, mutect2, varscan2
- PFKFB4 | chr3:48559529 T>C | 5'Flank (SNP) | VAF 16/325 reads (5%) | catalogued as rs1433357117; called by muse, mutect2
- POLD2 | c.-28G>T | 5'UTR (SNP) | VAF 10/78 reads (13%) | called by muse, varscan2
- POM121C | chr7:75416360 A>G | 3'Flank (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- REG3A | c.-10C>G | 5'UTR (SNP) | VAF 29/310 reads (9%) | called by muse, mutect2
- RGS5 | c.45-4221A>T | Intron (SNP) | VAF 75/412 reads (18%) | called by muse, mutect2, varscan2
- SEPTIN6 | chrX:119616545 G>A | 3'Flank (SNP) | VAF 50/564 reads (9%) | called by muse, mutect2
- SEPTIN6 | chrX:119616546 A>T | 3'Flank (SNP) | VAF 50/564 reads (9%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-47943G>T | Intron (SNP) | VAF 26/188 reads (14%) | catalogued as rs754338081, COSV67442734, COSV67447894; called by muse, mutect2, varscan2
- SYT14 | chr1:210163982 C>A | 3'Flank (SNP) | VAF 39/218 reads (18%) | called by muse, mutect2, varscan2
- ZNF99 | c.*651C>A | 3'UTR (SNP) | VAF 50/248 reads (20%) | called by muse, varscan2
- ZSCAN32 | c.915-106G>A | Intron (SNP) | VAF 182/825 reads (22%) | catalogued as COSV100514233; called by muse, mutect2, varscan2
